Somatic mutation profile of tumor specimen TCGA-F4-6460-01A (aliquot TCGA-F4-6460-01A-11D-1771-10) from TCGA case TCGA-F4-6460, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 51.0 years (18,637 days).
Specimen TCGA-F4-6460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3435904d-8623-4a56-a69f-f199e8cf83f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6460-10B (Blood Derived Normal), aliquot TCGA-F4-6460-10B-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2624f04f-3c99-4f93-91d7-ba73e26c03be

The open-access MAF lists 160 somatic variants for this specimen: 116 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 41, Nonsense Mutation 8, Splice Region 3, Frame Shift Del 1, Intron 1, 5'UTR 1, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 45/73 reads (62%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 37/66 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs371802545, COSV54518842; called by muse, mutect2, varscan2
- ACTA1 | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as COSV64204152; called by muse, mutect2, varscan2
- ADAMTS13 | c.3356C>G p.P1119R | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52471858; called by muse, mutect2, varscan2
- AP2A2 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100172339; called by muse, mutect2
- APOB | c.12389T>G p.F4130C | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99262847; called by muse, mutect2, varscan2
- ATP11A | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as rs745600009, COSV52107786; called by muse, mutect2, varscan2
- BRCA2 | c.615T>G p.S205R | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101203816; called by muse, mutect2, varscan2
- BRCA2 | c.4303A>C p.N1435H | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203817; called by muse, mutect2, varscan2
- BRWD3 | c.4352G>T p.R1451L | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100956244, COSV64753818; called by muse, mutect2, varscan2
- BTN1A1 | c.666T>A p.N222K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55069686; called by muse, mutect2, varscan2
- CCDC85A | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1052182749, COSV68155681; called by muse, mutect2, varscan2
- CD22 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as COSV50069617; called by muse, mutect2, varscan2
- CDH17 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99216773; called by muse, mutect2, varscan2
- CHST9 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV52449620; called by muse, mutect2, varscan2
- CLK4 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60321192; called by muse, mutect2, varscan2
- COG5 | c.1405G>T p.V469F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV51765065; called by muse, varscan2
- CUL3 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV52370706; called by muse, mutect2, varscan2
- DCAF12L2 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 127/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63583212, COSV63584206; called by muse, mutect2, varscan2
- DCAF4L2 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60479321, COSV60482779; called by muse, varscan2
- DCAF4L2 | c.435C>A p.C145* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100150359; called by muse, varscan2
- DCHS1 | c.3995C>G p.P1332R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.188); catalogued as COSV100201313; called by muse, mutect2, varscan2
- DNAH10 | c.13481C>G p.T4494S (on ENST00000409039; = p.T4433S on NM_207437.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53022345; called by muse, mutect2, varscan2
- DNTT | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1355861073, COSV64523709; called by muse, mutect2, varscan2
- DPP3 | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV64758103; called by muse, mutect2, varscan2
- DSC3 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs974085537, COSV100844369; called by muse, varscan2
- DST | c.4160G>A p.R1387Q (on ENST00000361203 / NM_001374722.1; = p.R1061Q on NM_001723.6) | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369264011; called by muse, mutect2, varscan2
- DZIP1L | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV59523609; called by muse, mutect2, varscan2
- EPHA6 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67594429, COSV99071794; called by muse, mutect2, varscan2
- FILIP1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs776109907, COSV52727020; called by muse, mutect2, varscan2
- FRMPD1 | c.3499G>C p.V1167L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV66700635, COSV66703242; called by muse, mutect2, varscan2
- GAS7 | c.315G>C p.W105C (on ENST00000432992 / NM_201433.2; = p.W45C on NM_201432.2) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100094103; called by muse, mutect2, varscan2
- GCNA | c.1520A>T p.K507M | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65468358; called by muse, mutect2, varscan2
- GOT2 | c.1019+2del p.X340_splice | Splice Site (DEL) | VAF 78/185 reads (42%) | catalogued as COSV55333461; called by mutect2, pindel, varscan2
- GRIA3 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52064265, COSV99988567; called by muse, mutect2, varscan2
- GTDC1 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99599062; called by muse, mutect2, varscan2
- HECTD4 | c.9185C>T p.P3062L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348349656, COSV66390854, COSV66392995; called by muse, mutect2, varscan2
- HHIPL1 | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs142621182, COSV58093626, COSV58094031; called by muse, mutect2, varscan2
- HLTF | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59503759; called by muse, mutect2, varscan2
- HPS1 | c.867G>A p.T289= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs770077009, COSV57270490; called by muse, mutect2, varscan2
- HTR7 | c.1191C>A p.S397R | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV53293140; called by muse, mutect2, varscan2
- IFNL3 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 78/163 reads (48%) | catalogued as rs777895796, COSV69830115, COSV69830222; called by muse, mutect2, varscan2
- INSL6 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV67563501; called by muse, mutect2, varscan2
- KCNJ12 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs139984724, COSV59167303; called by muse, mutect2
- KCNK9 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs753797613, COSV57283164; called by muse, mutect2, varscan2
- KCNQ3 | c.1982A>T p.K661M | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV66482514; called by muse, mutect2, varscan2
- KRT83 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs758485277, COSV53341321; called by muse, mutect2
- LCP2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs766513092, COSV99251830; called by muse, varscan2
- LDLRAD3 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 103/197 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs745429372, COSV59689332; called by muse, mutect2, varscan2
- LRFN5 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99981973; called by muse, mutect2, varscan2
- LRP1B | c.3653G>T p.C1218F | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101249893, COSV101256800; called by muse, mutect2, varscan2
- MACROD1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225268248, COSV99734438; called by muse, mutect2, varscan2
- MRGPRX3 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV101283460; called by muse, mutect2, varscan2
- MTREX | c.2501C>A p.S834Y | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV57930297; called by muse, mutect2
- MYH2 | c.1961C>A p.S654Y | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55448797; called by muse, mutect2, varscan2
- NCKAP1 | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62943832; called by muse, mutect2, varscan2
- NEXMIF | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV50024290, COSV50120902; called by muse, mutect2, varscan2
- OPCML | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as COSV100096727; called by muse, mutect2, varscan2
- OR10A3 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV62460311; called by muse, mutect2, varscan2
- OR51B4 | c.821G>C p.S274T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100970244, COSV66517603; called by muse, mutect2
- OR9G4 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100264943; called by muse, mutect2, varscan2
- PCDH8 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58815130; called by muse, mutect2, varscan2
- PCDHGB1 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1261429657, COSV54036847; called by muse, mutect2, varscan2
- PCDHGC5 | c.1920C>A p.D640E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV52750529; called by muse, mutect2
- PDE4DIP | c.4178A>G p.E1393G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57729828; called by muse, mutect2, varscan2
- PDE4DIP | c.4180A>T p.R1394* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV57729804; called by muse, mutect2, varscan2
- PHIP | c.3929G>A p.R1310H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs909398575, COSV51507022; called by muse, mutect2, varscan2
- PIP4K2A | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1169612513, COSV64865245; called by muse, mutect2, varscan2
- PIP5K1B | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV55258133; called by muse, mutect2, varscan2
- PLXNA3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781828247, COSV63753123; called by muse, mutect2, varscan2
- PRKAR1B | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs764518494, COSV64320093; called by muse, mutect2, varscan2
- PROX1 | c.1471T>C p.Y491H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99798480; called by muse, mutect2, varscan2
- PSG4 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 103/189 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs777453397, COSV54941155; called by muse, mutect2, varscan2
- RHOBTB1 | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1457224165, COSV61960251; called by muse, mutect2, varscan2
- RIMS2 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV101343959; called by muse, mutect2, varscan2
- RTN1 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs867180903, COSV99954276; called by muse, mutect2
- SCG2 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV100544557; called by muse, mutect2, varscan2
- SDK1 | c.4624A>T p.R1542* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV67389104; called by muse, mutect2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 41/113 reads (36%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SIRPB2 | c.839C>A p.A280E | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.055); catalogued as rs1429078700, COSV63125450, COSV63125574; called by muse, mutect2, varscan2
- SLC26A9 | c.951C>T p.R317= | Splice Region (SNP) | VAF 20/126 reads (16%) | catalogued as rs760498151, COSV61602677; called by muse, mutect2, varscan2
- SLC2A9 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV53329082, COSV53330702; called by muse, mutect2, varscan2
- SLC32A1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV54148425; called by muse, mutect2, varscan2
- SLC34A2 | c.1461C>T p.I487= | Splice Region (SNP) | VAF 51/138 reads (37%) | catalogued as rs867296079, COSV65942291; called by muse, mutect2, varscan2
- SLIT1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1046200407, COSV56599634; called by muse, mutect2, varscan2
- SOX2 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100327276, COSV57621515; called by muse, mutect2
- SPATA13 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57981582; called by muse, mutect2
- SSTR4 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs752836318, COSV54797852, COSV99658387; called by muse, mutect2, varscan2
- ST8SIA1 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV53952838, COSV53959438; called by muse, mutect2, varscan2
- STAU2 | c.865A>T p.K289* (on ENST00000524300 / NM_001164380.2; = p.K257* on NM_014393.2) | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as rs772293710, COSV63312108; called by muse, mutect2, varscan2
- SYNE1 | c.7400C>T p.T2467I (on ENST00000367255 / NM_182961.4; = p.T2474I on NM_033071.3) | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99549701; called by muse, mutect2, varscan2
- TENM4 | c.7151C>G p.A2384G | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV53672396; called by muse, mutect2, varscan2
- TG | c.6554G>A p.R2185Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs148004631, COSV55063976; called by muse, mutect2, varscan2
- TM4SF5 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199806115, COSV54498070; called by muse, mutect2, varscan2
- TMC3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143697026; called by muse, mutect2, varscan2
- TRIM54 | c.874G>A p.A292T (on ENST00000380075 / NM_187841.3; = p.A334T on NM_032546.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV51992107; called by muse, mutect2, varscan2
- TRPC4 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as COSV59007119; called by muse, mutect2, varscan2
- TRPM6 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV100664918, COSV62514472; called by muse, mutect2, varscan2
- TTC14 | c.2310T>A p.N770K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56014304; called by muse, mutect2, varscan2
- TTLL2 | c.864T>A p.S288R | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV53445988; called by muse, mutect2, varscan2
- TUB | c.664G>T p.A222S (on ENST00000299506 / NM_177972.3; = p.A277S on NM_003320.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV55110129; called by muse, mutect2, varscan2
- TWNK | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV52966822; called by muse, mutect2, varscan2
- UBQLNL | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV66493562, COSV66493838; called by muse, mutect2, varscan2
- ZBTB2 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57314152; called by muse, mutect2, varscan2
- ZC3H13 | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV99667260; called by muse, mutect2, varscan2
- ZNF480 | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.454); catalogued as COSV57998437; called by muse, mutect2, varscan2
- ZNF614 | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV99571601; called by muse, mutect2, varscan2
- ZNF676 | c.1594A>T p.T532S (on ENST00000650058; = p.T500S on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV101236069; called by muse, mutect2, varscan2
- ZNF766 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1043258106, COSV100765235; called by muse, mutect2
- ZNF804A | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV56451713, COSV56472084; called by muse, mutect2, varscan2
- HDLBP | c.2657G>T p.R886L | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PDS5A | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.108); called by muse, mutect2
- TNR | c.2605G>C p.D869H | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2
- TTN | c.64662del p.D21555Ifs*6 (on ENST00000591111; = p.D14131Ifs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 75/268 reads (28%) | called by mutect2, pindel, varscan2
- ZNF607 | c.1464_1465del p.Y488* | Nonsense Mutation (DEL) | VAF 9/82 reads (11%) | called by pindel, varscan2
- ANK2 | c.8139C>T p.V2713= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs564510599, COSV52174749; ClinVar: likely benign; called by muse, mutect2, varscan2
- APPL1 | c.2073C>T p.S691= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV55703725; called by muse, mutect2, varscan2
- ARG2 | c.1044T>C p.N348= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV53620851; called by muse, mutect2, varscan2
- ASCC3 | c.1245A>G p.T415= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1341793050, COSV61233925; called by muse, mutect2, varscan2
- BRWD3 | c.1980G>T p.L660= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as COSV64753824; called by muse, mutect2, varscan2
- C1orf52 | c.135G>A p.A45= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs953565269, COSV99640844; called by muse, mutect2
- CFAP69 | c.561G>A p.K187= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV100289655; called by muse, mutect2
- COL12A1 | c.6168G>A p.R2056= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV100485125; called by muse, mutect2
- DYRK1B | c.15G>A p.P5= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs182863590; called by muse, mutect2, varscan2
- EFCAB12 | c.1467G>A p.L489= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV58178935; called by muse, mutect2, varscan2
- FILIP1 | c.2013G>A p.Q671= | Silent (SNP) | VAF 41/222 reads (18%) | catalogued as COSV52741100; called by muse, mutect2, varscan2
- FOXD4L4 | c.204G>A p.A68= | Silent (SNP) | VAF 34/560 reads (6%) | called by muse, mutect2
- FOXD4L5 | c.204G>A p.A68= | Silent (SNP) | VAF 36/245 reads (15%) | catalogued as rs762262426, COSV101072986; called by muse, mutect2, varscan2
- GBP3 | c.213G>T p.V71= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV52520077; called by muse, mutect2, varscan2
- GGN | c.1734C>T p.R578= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs145112886; called by muse, mutect2, varscan2
- GNG7 | c.183C>T p.D61= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1451057662, COSV66288218; called by muse, mutect2, varscan2
- KCNT2 | c.69G>T p.G23= | Silent (SNP) | VAF 49/207 reads (24%) | catalogued as COSV54083444, COSV54109827; called by muse, mutect2, varscan2
- KIAA1109 | c.7809C>T p.S2603= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV52692850; called by muse, mutect2, varscan2
- KLHDC8A | c.876C>T p.V292= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV65679382; called by muse, mutect2, varscan2
- KRBA1 | c.219G>A p.E73= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99752067; called by muse, mutect2, varscan2
- LRRK2 | c.5080C>T p.L1694= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs746878736, COSV54171438; called by muse, mutect2, varscan2
- NIBAN1 | c.1620C>G p.V540= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV62284661, COSV62287804; called by muse, mutect2, varscan2
- NRSN1 | c.288C>T p.A96= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as COSV65894640; called by muse, mutect2, varscan2
- OR13C5 | c.348C>T p.G116= | Silent (SNP) | VAF 81/327 reads (25%) | catalogued as rs768261171, COSV66165350; called by muse, mutect2, varscan2
- PALMD | c.1062G>A p.S354= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs374387839; called by muse, mutect2, varscan2
- PAPPA | c.4599G>T p.R1533= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV60292166; called by muse, mutect2, varscan2
- PCDHAC2 | c.555C>T p.Y185= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs985147302, COSV53870995; called by muse, mutect2, varscan2
- PCED1B | c.831G>T p.G277= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101423585; called by muse, mutect2, varscan2
- PDE1B | c.210C>A p.V70= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV54496452; called by muse, mutect2, varscan2
- RIMS2 | c.1857T>C p.F619= (on ENST00000666250 / NM_001348490.2; = p.F427= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99153707; called by muse, mutect2, varscan2
- SBF1 | c.4800C>T p.P1600= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs778092683, COSV62370493; called by muse, mutect2, varscan2
- SFTPD | c.438A>G p.E146= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100954460; called by muse, mutect2, varscan2
- SIRT6 | c.483C>T p.A161= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs990861325, COSV50274471; called by muse, mutect2, varscan2
- SLC45A1 | c.645C>T p.H215= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as rs775874508, COSV57096099; called by muse, mutect2, varscan2
- SLITRK4 | c.1122G>A p.P374= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs782741851, COSV62023011; called by muse, mutect2, varscan2
- SRD5A2 | c.75G>A p.L25= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs782168484, COSV99252140; called by muse, mutect2, varscan2
- STAB1 | c.2817C>T p.A939= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs778143328, COSV100401919, COSV58743307; called by muse, mutect2, varscan2
- TEX26 | c.126A>G p.G42= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV66841038; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.753C>T p.H251= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs904099295, COSV59529592; called by muse, mutect2, varscan2
- ZFHX3 | c.7923C>T p.D2641= | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as rs148910628, COSV99194926; called by muse, mutect2, varscan2
- ZNF423 | c.1251T>C p.Y417= (on ENST00000563137 / NM_001379286.1; = p.Y409= on NM_015069.4) | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV52205171; called by muse, mutect2, varscan2
- AC005863.1 | n.279G>A | RNA (SNP) | VAF 43/112 reads (38%) | catalogued as rs1406203017; called by muse, mutect2, varscan2
- DNAH8 | c.-248C>T | 5'UTR (SNP) | VAF 16/83 reads (19%) | catalogued as COSV59463154, COSV59481511; called by muse, mutect2, varscan2
- GPC1 | c.167-3011G>A | Intron (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99882462; called by muse, mutect2, varscan2
